Somatic mutation profile of tumor specimen C3N-03802-01 (aliquot CPT0285260006) from CPTAC case C3N-03802, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.7 years (24,015 days).
Specimen C3N-03802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a2e8484-da42-4220-bb1e-5b8de2f69c94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03802-32 (Blood Derived Normal), aliquot CPT0280960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8341ca09-a9ab-4157-834f-2bdaf490f8c5

The open-access MAF lists 113 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 26, Nonsense Mutation 6, RNA 4, Splice Site 4, Intron 4, 3'UTR 3, 5'UTR 2, 5'Flank 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1007dup p.Y336* | Nonsense Mutation (INS) | VAF 52/92 reads (57%) | hotspot (GDC flag); catalogued as CI983205; called by mutect2, pindel, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 174/218 reads (80%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs757051527, COSV65907247, COSV65907403; called by muse, mutect2, varscan2
- ACE | c.3217C>T p.R1073C | Missense Mutation (SNP) | VAF 243/476 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762807750; called by muse, varscan2
- AHNAK2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1437160293, COSV60918612; called by muse, mutect2, varscan2
- ALDH2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 68/389 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs372053825; called by muse, mutect2, varscan2
- ASIC3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 237/783 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs150230080; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2258-1G>T p.X753_splice | Splice Site (SNP) | VAF 166/659 reads (25%) | catalogued as CS148446, COSV100022692; called by muse, mutect2, varscan2
- BRCA2 | c.7424A>G p.E2475G | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1358596567; called by muse, mutect2
- C12orf66 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.384); catalogued as rs1391163236; called by muse, mutect2
- CACNA1E | c.1549G>T p.G517* | Nonsense Mutation (SNP) | VAF 18/249 reads (7%) | catalogued as COSV100702073; called by muse, mutect2
- CELSR3 | c.6916G>A p.A2306T | Missense Mutation (SNP) | VAF 159/288 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs775336065, COSV50842302, COSV51134664; called by muse, mutect2, varscan2
- CRHR2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs548065920, COSV100793251; called by muse, mutect2, varscan2
- CSF1R | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs751557861, COSV53832205; called by muse, mutect2, varscan2
- DCAF8L2 | c.935A>T p.K312M | Missense Mutation (SNP) | VAF 164/197 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70549322; called by muse, mutect2, varscan2
- KCNB2 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as rs747398077; called by muse, mutect2, varscan2
- KCNC2 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 61/180 reads (34%) | catalogued as rs201449607, COSV54371409; called by muse, mutect2, varscan2
- KLRF2 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474905568; called by muse, mutect2, varscan2
- KSR2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373055394; called by muse, mutect2, varscan2
- L34079.1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 206/502 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs757597704, COSV60671027; called by muse, mutect2, varscan2
- LRBA | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143665533; called by muse, mutect2, varscan2
- LRP2 | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 213/482 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55564041, COSV55577469; called by muse, mutect2, varscan2
- NLRP7 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 210/476 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs748418867, COSV60180471; called by muse, mutect2, varscan2
- OR5T2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs770835107, COSV57589665, COSV57590384; called by muse, mutect2, varscan2
- PGAM4 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 20/314 reads (6%) | catalogued as COSV58454620; called by muse, mutect2
- PKD1L3 | c.585+1G>A p.X195_splice | Splice Site (SNP) | VAF 60/152 reads (39%) | catalogued as rs1313919180; called by muse, mutect2, varscan2
- PLCL2 | c.739C>T p.R247W (on ENST00000615277 / NM_001144382.2; = p.R121W on NM_015184.5) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101196570; called by muse, mutect2, varscan2
- PRG4 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201785504, COSV63355674, COSV63356193; called by muse, mutect2, varscan2
- RP1L1 | c.3461C>T p.S1154L | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775166574; called by muse, mutect2, varscan2
- SAGE1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1556605925, COSV61012029; called by muse, mutect2, varscan2
- SEC61A2 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100036271; called by muse, mutect2
- SH2D3C | c.1070G>A p.R357Q (on ENST00000314830 / NM_170600.3; = p.R200Q on NM_005489.4) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs745868179, COSV100137090; called by muse, mutect2, varscan2
- SLC1A6 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1473619679, COSV55671888; called by muse, mutect2
- TACC2 | c.5267C>T p.P1756L | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs764442622, COSV57749912; called by muse, mutect2, varscan2
- TRAV12-1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759731790; called by muse, mutect2, varscan2
- UNKL | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751264661, COSV100061810; called by muse, mutect2, varscan2
- ZNF804A | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762537446, COSV56437409; called by muse, mutect2, varscan2
- ABCA13 | c.2159A>G p.K720R | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); called by mutect2, varscan2
- ABHD16B | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AXL | c.1954T>A p.F652I (on ENST00000301178 / NM_021913.5; = p.F643I on NM_001699.6) | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CC2D1A | c.514-1G>A p.X172_splice | Splice Site (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- CELSR1 | c.1955A>T p.H652L | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- CNOT1 | c.6563C>T p.S2188L | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- COL3A1 | c.1510-6A>T | Splice Region (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DMD | c.8782A>G p.K2928E | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- EPPK1 | c.2345T>C p.L782P | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GALNT14 | c.298A>T p.R100* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- ITGAM | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- KLHL6 | c.643del p.V215Wfs*8 | Frame Shift Del (DEL) | VAF 253/594 reads (43%) | called by mutect2, pindel, varscan2
- KRT33A | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- KRTAP5-5 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 54/209 reads (26%) | PolyPhen benign (0.374); called by muse, varscan2
- L3MBTL3 | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB1 | c.3301G>T p.G1101W | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LNPK | c.813-1G>T p.X271_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- MANEA | c.850A>C p.T284P | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTR | c.1865A>G p.D622G | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- MYO1E | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 94/333 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52K1 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 155/456 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- PDE4A | c.850T>G p.S284A (on ENST00000380702 / NM_001111307.2; = p.S45A on NM_006202.3) | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- POU6F2 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.434T>G p.F145C (on ENST00000421990 / NM_001136042.2; = p.F127C on NM_025267.3) | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PTPRM | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SARDH | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF1 | c.1838T>A p.V613D | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SHANK1 | c.4721C>G p.S1574C | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- SLC1A3 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 124/575 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SSC5D | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 52/633 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SYPL1 | c.179T>G p.I60S | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TRIM38 | c.1081T>A p.L361I | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRPC7 | c.2108G>T p.R703I | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFYVE26 | c.5186T>G p.L1729R | Missense Mutation (SNP) | VAF 20/549 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC004593.2 | c.573T>G p.G191= | Silent (SNP) | VAF 114/407 reads (28%) | called by muse, mutect2, varscan2
- ARSJ | c.306T>A p.T102= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- BAZ2B | c.5565C>T p.D1855= | Silent (SNP) | VAF 93/456 reads (20%) | catalogued as rs746684021, COSV58607043; called by muse, mutect2, varscan2
- C1orf189 | c.135G>A p.P45= | Silent (SNP) | VAF 100/263 reads (38%) | catalogued as rs376522577; called by muse, mutect2, varscan2
- CCDC168 | c.14214A>G p.A4738= | Silent (SNP) | VAF 95/162 reads (59%) | called by muse, mutect2, varscan2
- CHTF18 | c.1488G>A p.P496= | Silent (SNP) | VAF 44/307 reads (14%) | catalogued as rs552756954, COSV50100539; called by muse, mutect2, varscan2
- DZANK1 | c.1059C>T p.C353= (on ENST00000262547 / NM_001099407.1; = p.C154= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs757627145, COSV99363342; called by muse, mutect2, varscan2
- FGD5 | c.1353C>T p.D451= | Silent (SNP) | VAF 275/441 reads (62%) | catalogued as rs374381042; called by muse, mutect2, varscan2
- GJA8 | c.150C>T p.S50= | Silent (SNP) | VAF 124/313 reads (40%) | called by muse, mutect2, varscan2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 88/307 reads (29%) | catalogued as rs368456046; called by muse, mutect2, varscan2
- IGHV4-61 | c.42C>A p.P14= | Silent (SNP) | VAF 110/791 reads (14%) | catalogued as rs373396693; called by muse, mutect2, varscan2
- IL9R | c.1476T>A p.A492= | Silent (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- KCNJ14 | c.585C>T p.N195= | Silent (SNP) | VAF 85/105 reads (81%) | catalogued as rs1354499722; called by muse, mutect2, varscan2
- KMT2C | c.7575T>G p.P2525= | Silent (SNP) | VAF 41/262 reads (16%) | called by muse, mutect2, varscan2
- MBLAC2 | c.519C>A p.G173= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV57302287; called by mutect2, varscan2
- ME2 | c.597G>A p.L199= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as rs147002611; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAIP | c.414C>T p.Y138= | Silent (SNP) | VAF 167/378 reads (44%) | catalogued as rs759032459, COSV52000721; called by muse, mutect2, varscan2
- OR6C74 | c.547C>T p.L183= | Silent (SNP) | VAF 12/378 reads (3%) | catalogued as COSV59605688, COSV59606913; called by muse, mutect2
- POP1 | c.27C>T p.H9= | Silent (SNP) | VAF 73/392 reads (19%) | catalogued as rs376017756; ClinVar: likely benign; called by muse, mutect2, varscan2
- PSG1 | c.255C>T p.D85= | Silent (SNP) | VAF 199/454 reads (44%) | catalogued as rs1058959, COSV54944619, COSV54949080; called by muse, mutect2, varscan2
- RFNG | c.876C>T p.N292= | Silent (SNP) | VAF 154/284 reads (54%) | catalogued as rs202024621; called by muse, mutect2, varscan2
- RFPL4AL1 | c.552C>T p.H184= | Silent (SNP) | VAF 346/1239 reads (28%) | catalogued as rs773290313; called by muse, varscan2
- SAGE1 | c.123A>G p.T41= | Silent (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- SH2B3 | c.378G>T p.P126= | Silent (SNP) | VAF 55/208 reads (26%) | called by muse, mutect2, varscan2
- SLC36A3 | c.1065G>T p.P355= | Silent (SNP) | VAF 87/230 reads (38%) | called by muse, mutect2, varscan2
- TBX3 | c.1839C>A p.A613= (on ENST00000257566 / NM_016569.4; = p.A593= on NM_005996.4) | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV57473490; called by muse, mutect2, varscan2
- BICDL2 | chr16:3036189 C>A | 5'Flank (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101199354; called by muse, mutect2, varscan2
- C7 | c.-1C>A | 5'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- CCNQP1 | n.518T>G | RNA (SNP) | VAF 173/427 reads (41%) | called by muse, mutect2, varscan2
- CRB1 | c.-27A>T | 5'UTR (SNP) | VAF 11/269 reads (4%) | called by muse, mutect2
- D2HGDH | c.*24G>T | 3'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- DEK | c.762+5094G>A | Intron (SNP) | VAF 106/259 reads (41%) | catalogued as rs777107826; called by muse, mutect2, varscan2
- EARS2 | c.296-1730T>C | Intron (SNP) | VAF 73/176 reads (41%) | catalogued as rs1304900985; called by muse, mutect2, varscan2
- FAM183BP | n.1007C>A | RNA (SNP) | VAF 162/626 reads (26%) | called by muse, mutect2, varscan2
- FAM74A3 | n.365G>A | RNA (SNP) | VAF 236/712 reads (33%) | catalogued as rs1275849448; called by muse, mutect2
- IGKV2-29 | n.258G>C | RNA (SNP) | VAF 170/574 reads (30%) | catalogued as rs1459166969; called by muse, varscan2
- LRRC27 | chr10:132331838 G>A | 5'Flank (SNP) | VAF 15/20 reads (75%) | catalogued as rs377650765; called by muse, mutect2, varscan2
- MAJIN | c.473+1278C>A | Intron (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- PCLO | c.14791+10G>A | Intron (SNP) | VAF 147/440 reads (33%) | catalogued as rs567145523, COSV61656544; called by muse, mutect2, varscan2
- SCN4B | c.*2926C>T | 3'UTR (SNP) | VAF 85/130 reads (65%) | called by muse, mutect2, varscan2
- TYK2 | c.*20C>G | 3'UTR (SNP) | VAF 102/237 reads (43%) | catalogued as rs765558684; called by muse, mutect2, varscan2
